Somatic mutation profile of tumor specimen MMRF_1349_1_BM_CD138pos (aliquot MMRF_1349_1_BM_CD138pos_T1_KAS5U_L01706) from MMRF case MMRF_1349, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.0 years (31,055 days).
Specimen MMRF_1349_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6debcb5c-bc54-4598-95f9-c752de137a10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1349_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1349_1_PB_Whole_C2_KAS5U_L01714; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ede87a9-9c90-4a29-bf8f-43c63c1233ae

The open-access MAF lists 108 somatic variants for this specimen: 48 protein-altering or splice-affecting, 7 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 29, Intron 13, Silent 7, 5'UTR 6, Nonsense Mutation 3, RNA 2, 3'Flank 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DKK2 | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 57/117 reads (49%) | catalogued as rs1470908751, COSV53395610; called by muse, mutect2, varscan2
- DTX1 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445157568; called by muse, varscan2
- FGFR3 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53426972, COSV99603109; called by muse, mutect2, varscan2
- GATM | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751757258, COSV67540297; called by muse, mutect2, varscan2
- GREB1L | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52562339; called by muse, mutect2, varscan2
- HHAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 156/250 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs143700139; called by muse, mutect2, varscan2
- HNRNPC | c.626C>A p.S209Y (on ENST00000420743; = p.S196Y on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs764927549, COSV100192860, COSV60146507; called by muse, mutect2
- LIMA1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 108/117 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV57963718; called by muse, mutect2, varscan2
- LNPEP | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1561441965, COSV99183473; called by muse, mutect2, varscan2
- MUC12 | c.755C>A p.P252H (on ENST00000379442; = p.P109H on NM_001164462.1) | Missense Mutation (SNP) | VAF 143/275 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.715); catalogued as rs923305839; called by muse, mutect2, varscan2
- NELL1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 170/397 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1327462504; called by muse, mutect2, varscan2
- OR5F1 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs1276176593; called by muse, mutect2, varscan2
- PSMB6 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54512607; called by muse, mutect2, varscan2
- SLC3A1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs767848933, CD148312, COSV99576796; called by muse, mutect2, varscan2
- SPTBN5 | c.7471G>A p.A2491T | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs768899058; called by muse, mutect2, varscan2
- TMEM207 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as COSV61562205; called by muse, mutect2, varscan2
- ZNF208 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.787); catalogued as COSV68101302; called by muse, mutect2, varscan2
- ZNF354B | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs768014242; called by muse, mutect2
- AKAP3 | c.2183C>A p.A728D | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ARHGAP1 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP17 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATG5 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- B4GALT5 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC166 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CCDC168 | c.12895G>C p.G4299R | Missense Mutation (SNP) | VAF 208/211 reads (99%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CPEB3 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- DIS3 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 48/49 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EIF2B2 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- FYTTD1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- IL1RAP | c.1145G>A p.W382* | Nonsense Mutation (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- IVL | c.1740G>A p.W580* | Nonsense Mutation (SNP) | VAF 10/251 reads (4%) | called by muse, mutect2
- KLHL22 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAGI2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MMUT | c.146del p.K49Sfs*3 | Frame Shift Del (DEL) | VAF 65/120 reads (54%) | called by mutect2, varscan2
- MTA2 | c.684T>G p.D228E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PASK | c.3592T>A p.F1198I | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH18 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PDE1C | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.131); called by muse, mutect2
- PPP1R12B | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAPGEF2 | c.3378G>T p.R1126S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SPPL2C | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STIL | c.2925C>A p.N975K | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SUSD2 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TACR2 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TMEM176A | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRIO | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 163/333 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- UBR3 | c.1295A>G p.K432R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- XPO1 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1A1 | c.738T>A p.A246= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CFAP46 | c.4998G>A p.Q1666= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs1173373765; called by muse, mutect2, varscan2
- IGLC2 | c.321G>A p.*107= | Silent (SNP) | VAF 73/478 reads (15%) | called by muse, mutect2, varscan2
- KCNK16 | c.345A>T p.A115= | Silent (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- MYO7B | c.1749C>T p.S583= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs761594831, COSV67346797; called by muse, mutect2, varscan2
- PARVA | c.279G>A p.K93= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs1298104563; called by muse, mutect2, varscan2
- RBFOX2 | c.267C>T p.D89= (on ENST00000438146 / NM_001349995.2; = p.D19= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 193/403 reads (48%) | catalogued as rs549636175; called by muse, mutect2, varscan2
- ACER3 | c.215-142A>G | Intron (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- ACSL3 | c.*1458_*1459insCAA | 3'UTR (INS) | VAF 38/69 reads (55%) | catalogued as rs66647824; called by mutect2, varscan2*
- ADCY6 | c.*1442A>G | 3'UTR (SNP) | VAF 72/74 reads (97%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*258G>A | 3'UTR (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+994del | Intron (DEL) | VAF 36/80 reads (45%) | catalogued as rs199892132; called by mutect2, varscan2
- ASB6 | c.*21C>T | 3'UTR (SNP) | VAF 31/93 reads (33%) | catalogued as rs375847126; called by muse, mutect2, varscan2
- ATP5MPL | c.148+255G>A | Intron (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*3663T>C | 3'UTR (SNP) | VAF 64/64 reads (100%) | called by muse, mutect2, varscan2
- CDC23 | c.372+515A>T | Intron (SNP) | VAF 50/113 reads (44%) | catalogued as rs1206601098; called by muse, mutect2, varscan2
- CTNNA2 | c.*530G>A | 3'UTR (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- DTX1 | c.-298C>T | 5'UTR (SNP) | VAF 55/111 reads (50%) | catalogued as COSV57499830; called by muse, mutect2, varscan2
- DTX1 | c.-76T>A | 5'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- EFCAB2 | chr1:244969963 C>T | 5'Flank (SNP) | VAF 54/157 reads (34%) | called by muse, mutect2, varscan2
- ENOPH1 | c.-222G>A | 5'UTR (SNP) | VAF 15/136 reads (11%) | catalogued as rs966732827; called by muse, mutect2, varscan2
- FRY | c.71-17747G>A | Intron (SNP) | VAF 217/225 reads (96%) | called by muse, mutect2, varscan2
- GDA | c.*1726T>C | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- GLI3 | c.*2656G>C | 3'UTR (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- GPATCH2 | c.*934G>C | 3'UTR (SNP) | VAF 121/202 reads (60%) | called by muse, mutect2, varscan2
- GULP1 | c.*1689A>G | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- HOMEZ | c.*2764del | 3'UTR (DEL) | VAF 44/89 reads (49%) | called by mutect2, pindel, varscan2
- JPH3 | chr16:87700936 del CTTCTCTC | 3'Flank (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- KCNT2 | c.*1941A>T | 3'UTR (SNP) | VAF 179/266 reads (67%) | called by muse, mutect2, varscan2
- KCTD3 | c.*94C>T | 3'UTR (SNP) | VAF 34/144 reads (24%) | catalogued as rs887609808; called by muse, mutect2, varscan2
- LRRC38 | c.*108C>G | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- LTB | c.162+112C>G | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- LYPD6 | c.*2707G>C | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- MFSD9 | c.*2113G>A | 3'UTR (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- NFX1 | c.*242A>G | 3'UTR (SNP) | VAF 56/104 reads (54%) | catalogued as rs934334429; called by muse, mutect2, varscan2
- NLGN1 | c.*2697C>T | 3'UTR (SNP) | VAF 58/128 reads (45%) | catalogued as rs1300220163; called by muse, mutect2, varscan2
- NLRP12 | c.2073-144del | Intron (DEL) | VAF 9/22 reads (41%) | called by mutect2, varscan2
- NPHP1 | c.*334del | 3'UTR (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- NRIP2 | c.*1170A>C | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- OXGR1 | c.*909T>A | 3'UTR (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- PATE1 | c.52+26T>A | Intron (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- PCDH11X | c.-228C>T | 5'UTR (SNP) | VAF 49/82 reads (60%) | called by muse, mutect2, varscan2
- PCLO | c.14791+424A>T | Intron (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- PJVK | c.211+28C>G | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.204+89T>G | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- PROCA1 | chr17:28703335 G>T | 3'Flank (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- RAB6B | c.-186T>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- RASGRF2 | c.*3062C>T | 3'UTR (SNP) | VAF 83/184 reads (45%) | catalogued as rs943173866; called by muse, mutect2, varscan2
- RBM18 | c.*403T>G | 3'UTR (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- RBMS1 | c.*7+85G>A | Intron (SNP) | VAF 133/380 reads (35%) | called by muse, mutect2, varscan2
- RELA | c.*172C>T | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- RNFT2 | c.*2688C>T | 3'UTR (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.*1631G>A | 3'UTR (SNP) | VAF 48/88 reads (55%) | called by muse, mutect2, varscan2
- SSPOP | n.9288C>T | RNA (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- TBC1D19 | c.-149G>C | 5'UTR (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- TMEM245 | c.*3922G>T | 3'UTR (SNP) | VAF 91/211 reads (43%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.1191G>A | RNA (SNP) | VAF 12/32 reads (38%) | catalogued as rs1334147846; called by muse, varscan2
- UHRF1BP1 | c.*513A>C | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- ZNF420 | c.137-12004G>A | Intron (SNP) | VAF 53/112 reads (47%) | catalogued as rs997887891; called by muse, mutect2, varscan2
- ZNF536 | c.*123A>T | 3'UTR (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
